Somatic mutation profile of tumor specimen C3L-01665-03 (aliquot CPT0104500009) from CPTAC case C3L-01665, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 67.5 years (24,663 days).
Specimen C3L-01665-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8bd5fc9-ab6b-4e2c-a43f-58fd21411a7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01665-31 (Blood Derived Normal), aliquot CPT0105140002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d507698-d01f-4af3-8ccd-8ecf1d3acb6c

The open-access MAF lists 90 somatic variants for this specimen: 67 protein-altering or splice-affecting, 12 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 12, Frame Shift Del 9, Intron 8, In Frame Del 6, Frame Shift Ins 3, Nonsense Mutation 1, Splice Region 1, RNA 1, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA13 | c.1553C>T p.P518L | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as rs570096958; called by muse, mutect2, varscan2
- APOL2 | c.157C>T p.R53C | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as rs199839971, COSV99969205; called by muse, mutect2, varscan2
- BST1 | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 56/240 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.027); catalogued as rs749934523; called by mutect2, varscan2
- FTMT | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1268012673, COSV58419632; called by muse, mutect2, varscan2
- GRK4 | c.868G>A p.V290I (on ENST00000398052 / NM_182982.3; = p.V258I on NM_005307.3) | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.033); catalogued as rs545770050; called by muse, mutect2, varscan2
- HHAT | c.848G>T p.W283L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV99805541; called by muse, mutect2
- HOXC13 | c.591C>G p.I197M | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as rs748076826; called by muse, mutect2, varscan2
- IRGC | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs757989962; called by muse, mutect2, varscan2
- NIBAN3 | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as COSV99961870; called by muse, mutect2, varscan2
- NLRP2 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 72/326 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV54756444; called by muse, mutect2, varscan2
- PDLIM7 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as rs1303799262, COSV63080588; called by muse, mutect2, varscan2
- RIC1 | c.4195C>T p.R1399W | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs376378176; called by muse, mutect2, varscan2
- SETD2 | c.3199C>T p.Q1067* | Nonsense Mutation (SNP) | VAF 48/144 reads (33%) | catalogued as COSV57439237; called by muse, mutect2, varscan2
- SLC26A4 | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 70/373 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs138816005, COSV55918385; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SRD5A1 | c.108_109del p.Y38Rfs*89 | Frame Shift Del (DEL) | VAF 43/282 reads (15%) | catalogued as rs1489726635; called by mutect2, pindel, varscan2
- U2SURP | c.2089G>A p.A697T | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as rs1364619257, COSV101204322, COSV67532018; called by muse, mutect2, varscan2
- VHL | c.494T>A p.V165D | Missense Mutation (SNP) | VAF 116/396 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as HM971603, COSV56546432; called by muse, mutect2, varscan2
- AC053503.6 | c.1006_1016del p.F337Rfs*? | Frame Shift Del (DEL) | VAF 26/120 reads (22%) | called by mutect2, pindel*, varscan2
- ADIPOR2 | c.907C>T p.L303F | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.91); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANKRD30A | c.212C>T p.A71V (on ENST00000611781; = p.A15V on NM_052997.2) | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- CBLN4 | c.56C>G p.T19R | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDH9 | c.1538A>G p.D513G | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CEP350 | c.6236A>G p.Q2079R | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- CNOT6 | c.1253_1254insG p.D418Efs*21 | Frame Shift Ins (INS) | VAF 39/164 reads (24%) | called by mutect2, pindel*, varscan2
- COG3 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 43/186 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPXCR1 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CRYGC | c.464_468del p.Q155Lfs*7 | Frame Shift Del (DEL) | VAF 56/259 reads (22%) | called by mutect2, pindel, varscan2
- CYP20A1 | c.386A>C p.N129T | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- DOLK | c.719dup p.F241Lfs*115 | Frame Shift Ins (INS) | VAF 63/243 reads (26%) | called by mutect2, pindel, varscan2
- ECPAS | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FCHO1 | c.1795G>A p.E599K | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FLG2 | c.1853A>G p.Y618C | Missense Mutation (SNP) | VAF 109/359 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FPGT | c.1395del p.F465Lfs*5 | Frame Shift Del (DEL) | VAF 69/338 reads (20%) | called by mutect2, pindel, varscan2
- IZUMO2 | c.426del p.E143Kfs*86 | Frame Shift Del (DEL) | VAF 27/161 reads (17%) | called by mutect2, pindel, varscan2
- KIF26A | c.5050G>T p.G1684W | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- LIN37 | c.273_277+1del | In Frame Del (DEL) | VAF 27/91 reads (30%) | called by mutect2, pindel, varscan2
- MARCHF7 | c.1097C>G p.S366C | Missense Mutation (SNP) | VAF 50/251 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- MYT1 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NEUROD4 | c.238_239delinsA p.A80Ifs*24 | Frame Shift Del (DEL) | VAF 53/405 reads (13%) | called by pindel, varscan2*
- PARD3B | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PBRM1 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCSK6 | c.531del p.N177Kfs*8 | Frame Shift Del (DEL) | VAF 44/244 reads (18%) | called by mutect2, pindel, varscan2
- PGS1 | c.1315T>G p.F439V | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLCG2 | c.930C>A p.D310E | Missense Mutation (SNP) | VAF 53/170 reads (31%) | SIFT tolerated (0.62); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLCL1 | c.1267A>T p.R423W | Missense Mutation (SNP) | VAF 43/191 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PLEKHA5 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 66/276 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- PLEKHM1 | c.2261T>A p.V754D | Missense Mutation (SNP) | VAF 81/438 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- PON1 | c.75-7C>T | Splice Region (SNP) | VAF 9/254 reads (4%) | called by muse, mutect2
- PON3 | c.663_664del p.A222Qfs*16 | Frame Shift Del (DEL) | VAF 89/406 reads (22%) | called by mutect2, pindel, varscan2
- PPP2R5A | c.1403A>G p.E468G | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- PRPF39 | c.1347A>T p.E449D | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SH3BGRL3 | c.97A>G p.I33V | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- SLAMF9 | c.567G>T p.W189C | Missense Mutation (SNP) | VAF 78/377 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC17A9 | c.934_942del p.K312_M314del | In Frame Del (DEL) | VAF 23/210 reads (11%) | called by mutect2, pindel, varscan2
- SLC25A11 | c.333_341del p.A112_G114del | In Frame Del (DEL) | VAF 26/212 reads (12%) | called by pindel, varscan2*
- SLC25A3 | c.128C>A p.P43H | Missense Mutation (SNP) | VAF 62/261 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC26A9 | c.986_988del p.Q329_W330delinsR | In Frame Del (DEL) | VAF 29/129 reads (22%) | called by mutect2, pindel, varscan2
- SLC4A11 | c.1217A>G p.D406G | Missense Mutation (SNP) | VAF 115/476 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- SLC7A14 | c.1915del p.A639Pfs*4 | Frame Shift Del (DEL) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- SNCAIP | c.1642_1643dup p.A549Kfs*37 | Frame Shift Ins (INS) | VAF 58/266 reads (22%) | called by mutect2, pindel, varscan2
- STX6 | c.380G>C p.S127T | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- TCF21 | c.412G>T p.D138Y | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TMEM59 | c.912A>C p.E304D | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM87B | c.399A>C p.K133N | Missense Mutation (SNP) | VAF 66/263 reads (25%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- WDR17 | c.2044_2046del p.L682del | In Frame Del (DEL) | VAF 45/270 reads (17%) | called by mutect2, pindel*, varscan2*
- WDR35 | c.2925_2939del p.L976_Q980del (on ENST00000345530 / NM_001006657.2; = p.L965_Q969del on NM_020779.4) | In Frame Del (DEL) | VAF 65/304 reads (21%) | called by mutect2, pindel, varscan2
- ZGRF1 | c.3193C>G p.Q1065E | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDX2 | c.600G>A p.E200= | Silent (SNP) | VAF 45/212 reads (21%) | catalogued as COSV66829155; called by muse, mutect2, varscan2
- CEP350 | c.6237A>G p.Q2079= | Silent (SNP) | VAF 26/157 reads (17%) | catalogued as rs1455664052; called by muse, mutect2, varscan2
- IDO1 | c.273G>A p.V91= | Silent (SNP) | VAF 36/145 reads (25%) | called by muse, mutect2, varscan2
- KBTBD7 | c.165C>T p.S55= | Silent (SNP) | VAF 86/297 reads (29%) | catalogued as COSV65267178; called by muse, mutect2, varscan2
- KL | c.2541A>G p.V847= | Silent (SNP) | VAF 71/261 reads (27%) | called by muse, mutect2, varscan2
- LCK | c.372C>T p.P124= | Silent (SNP) | VAF 61/251 reads (24%) | catalogued as rs748136140; called by muse, mutect2, varscan2
- MED13 | c.681A>C p.S227= | Silent (SNP) | VAF 49/294 reads (17%) | catalogued as COSV63228643; called by muse, mutect2, varscan2
- MUC22 | c.4677A>G p.R1559= | Silent (SNP) | VAF 34/132 reads (26%) | called by muse, mutect2
- NRCAM | c.3348T>C p.G1116= | Silent (SNP) | VAF 49/165 reads (30%) | called by muse, mutect2, varscan2
- SLC35D2 | c.453C>G p.V151= | Silent (SNP) | VAF 44/224 reads (20%) | called by muse, mutect2, varscan2
- UBR4 | c.198T>C p.H66= | Silent (SNP) | VAF 33/168 reads (20%) | called by muse, mutect2, varscan2
- ZC3H10 | c.42C>T p.S14= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs745515239; called by mutect2, varscan2
- CAPZA2 | c.507-36C>G | Intron (SNP) | VAF 53/211 reads (25%) | called by muse, mutect2, varscan2
- FBRS | chr16:30660286 A>C | 5'Flank (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- HAL | c.248-14G>A | Intron (SNP) | VAF 84/384 reads (22%) | catalogued as rs751044169; called by muse, mutect2, varscan2
- IFT22 | c.409+23del | Intron (DEL) | VAF 32/162 reads (20%) | called by mutect2, pindel
- IL2RB | c.204-191G>A | Intron (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- MBD3 | c.*2922G>C | 3'UTR (SNP) | VAF 7/42 reads (17%) | called by muse, mutect2, varscan2
- NEK1 | c.1562+43T>A | Intron (SNP) | VAF 67/287 reads (23%) | called by muse, mutect2, varscan2
- NRP1 | c.1864+57G>A | Intron (SNP) | VAF 44/210 reads (21%) | called by muse, mutect2, varscan2
- NTN1 | c.1411+367C>A | Intron (SNP) | VAF 26/131 reads (20%) | called by muse, mutect2, varscan2
- TMEM75 | n.686_709del | RNA (DEL) | VAF 18/70 reads (26%) | called by mutect2, pindel
- ZFYVE28 | c.701+6601A>G | Intron (SNP) | VAF 22/127 reads (17%) | catalogued as rs996729311; called by muse, mutect2, varscan2
